Surgical pathology report (de-identified scan), TCGA case TCGA-31-1951, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Imperial College, specimen TCGA-31-1951-01A (Primary Tumor).

[page 1 of 4]
Specimen Type:

- 1: Omentum + SPLEEN
- 2: PELVIC PERITONEUM DEPOSIT
- 3: LEFT OVARY
- 4: Uterus, RIGHT OVARY, CERVIX, PERITONEAL DEPOSIT
- 5: BOWEL RESECTION
- 6: Colon resection TERMINAL ILEUM AND CAECUM

TCGA-31-1951

Clinical Details:

Ovarian cancer. Splenectomy and right hemicolectomy for ovarian primary Stage 4 disease.

Macroscopic Description:

1) Omentum and spleen:

A spleen with attached peritoneum received, the spleen measures 10 x 6 x 3cm and the attached peritoneum measures 30 x 19 x 2cm. There is a capsular tear on the surface of the spleen measuring 1cm in maximum dimension. The peritoneal fat shows multiple hard nodular areas, query metastatic deposits, the largest area measures 6 x 4 x 2.5cm. The cut surface of these nodular areas reveals firm white solid areas. The cut surface of the spleen shows spongy haemorrhagic area. The attached omentum on the anterior surface of the spleen shows tumour deposits which abut the anterior surface of the spleen, these deposits measure 1.5 x 1 x 0.8cm.

BLOCKS: 1A-C: RS omentum: 1pc in each.

1D: Spleen with attached peritoneum with tumour deposit: 1,1pc

2) Pelvic peritoneum deposit:

Two pieces of firm fibrofatty tissue measuring 3.5 x 2 x 1cm and 2.5 x 0.8 x 0.3cm. Slicing reveals a firm white deposit.

BLOCKS: 2A-C: Larger piece: 1pc in each.

2D: Smaller piece: 1,1pc

[page 2 of 4]
3) Left ovary:

An ovary with attached tube, the fallopian tube measures 5cm length and 1.5cm in diameter. The outer surface of the ovary is multinodular, there are also some fine papillary projections on the surface. The cut surface of the ovary shows solid white firm areas. The ovary measures 4.5 x 4.5 x 4cm. Also received in the same pot are multiple nodular pieces of tissue together measuring 5 x 3 x 1cm.

BLOCKS: 3A: RS ovary: 1,1pc.
3B: RS ovary and papillary projection: 1,1pc.
3C: RS ovary and tube: 1,1pc.
3D-E: RS ovary: 1pc in each.
3F-G: Fallopian tube: 1pc in each.
3H-K: RS separate nodular tissue: 1pc in each.

TCGA-31-1951

4) Uterus, right ovary, cervix and peritoneal deposit:

A specimen of uterus, cervix with attached right adnexa received, the uterus measures 8 x 4.5 x 3cm. The right fallopian tube measures 5cm in length and 0.6cm in diameter, the right ovary measures 3.5 x 1.5 x 0.6cm. The outer surface of the uterus shows multiple nodular deposits on the fundal surface, the largest deposit measures 2.5 x 1.5cm. Slicing reveals a slit like uterine cavity. Slicing of the nodular deposit on the fundus of the uterus reveals a firm yellow area. Also received in the same pot are separate pieces of firm fibrofatty tissue measuring together 7 x 6 x 2cm. One of the pieces show an attached vesicle measuring 1.2 x 0.8cm. The myometrial thickness is 1.4cm and the endometrial thickness is 0.2cm. The anterior surface of the uterus is painted black and the posterior blue.

BLOCKS: 4A: Anterior cervix: 1,1pc.
4B: Posterior cervix: 1,1pc.
4C: Lower uterine segment: 1,1pc.
4D: Endometrium and myometrium: 1,1pc.
4E-F: Nodular deposit on anterior wall: 1pc in each.
4G-H: Ovary: 1pc in each.
4J: TS fallopian tube: 1,3pcs.
4K: Separate nodular deposit plus cyst: 1,1pc.
4L-M: Separate deposit: 1pc in each. NAE.

5) Large bowel:

A loop of segment of bowel measuring 11cm in length and 7cm in diameter. There are multiple nodular deposits on the outer surface of the wall, the largest measuring 1cm in diameter. Also noted is a firm deposit with attached peritoneal fat measuring 4 x 2 x 1cm. The mucosal surface appears normal.

BLOCKS: 5A-B: Resection margins: 1pc in each.
5C-D: Nodular deposit with bowel wall: 1pc in each.
5E: Nodular deposit with attached fat: 1,1pc.

6) Terminal ileum and caecum:

[page 3 of 4]
A segment of bowel measuring 8cm in length and 1cm in diameter. The mucosa appears normal, no lesions or metastatic tumour deposits are seen. The bowel is stapled at both end. No caecum is identified.

BLOCKS: 6A-B: Resection margins: 1pc in each.
6C: Random TS: 1,2pcs.

Microscopic Description:

1) OMENTUM & SPLEEN

The omental fat shows metastatic deposits of poorly differentiated adenocarcinoma, the largest deposit being 6 cm in maximum diameter. The tumour focally invades the spleen from the external surface. Angiovascular invasion is identified.

2) PELVIC PERITONEUM DEPOSIT

The peritoneal fat shows multiple metastatic deposits of poorly differentiated adenocarcinoma with necrosis and desmoplastic reaction. The largest deposit is 3.8 cm in maximum dimension. A single lymph node extensively involved with tumour is seen, with lymphovascular invasion.

3) LEFT OVARY

The left ovarian mass is a poorly differentiated, grade 3 serous adenocarcinoma, extensively replacing the ovary and the attached fallopian tube.

The tumour is composed of predominantly solid sheets of highly atypical epithelial cells with focal papillary formations. Frequent atypical mitoses and necrosis are present. Occasional calcification are noted. The tumour extends to the adherent omental fat tissue with marked desmoplastic reaction.

4) UTERUS, RIGHT OVARY, CERVIX & PERITONEAL DEPOSIT

The uterus shows multiple deposits of poorly differentiated adenocarcinoma, invading the uterine wall from the external surface.

The endometrium is atrophic. Multiple foci of adenomyosis are noted in the uterus. The cervix shows Nabothian cyst, but does not show involvement by tumour. The right ovary and fallopian tube are intact but loose deposits of tumour are identified on the outer surface, partially as detached fragments.

5) LARGE BOWEL

The large bowel shows multiple deposits of metastatic poorly differentiated adenocarcinoma, invading the muscularis propria and reaching the submucosa.

The resection margins are free from tumour.

6) TERMINAL ILEUM & CAECUM

The small bowel shows no evidence of metastatic malignancy. The resection margins are free from tumour.

TCGA-31-1951

[page 4 of 4]
Final Diagnosis:

LEFT OVARY: POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA METASTATIC TO OMENTUM, SPLEEN, UTERINE SEROSA, MYOMETRIUM AND BOWEL
STAGE 3C

Additional Pathologist(s)/BMS(s)

[REDACTED]

[REDACTED]

TCGA-31-1951

Procedures/Addenda:

Immunocytochemistry

Date Ordered:

Date Complete:

Date Reported:

[REDACTED]

Interpretation

The findings are consistent with serous papillary adenocarcinoma.

Results-Comments

Where viable and well preserved the tumour cells reactly strongly with ER, WT1 and p53 antisera. PgR is negative

Source: NCI Genomic Data Commons file d39d914a-1e71-4da3-842c-7815e0f0d782 (TCGA-31-1951.B10EFE75-1420-47D2-9C5B-202B09099357.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).